Somatic mutation profile of tumor specimen TCGA-44-8117-01A (aliquot TCGA-44-8117-01A-11D-2238-08) from TCGA case TCGA-44-8117, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.4 years (19,855 days).
Specimen TCGA-44-8117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 416a2436-c5f4-4fae-a3e2-f1c3729b16fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-8117-10A (Blood Derived Normal), aliquot TCGA-44-8117-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8a15a3a-3de9-4d52-8db3-c4c8eed7d188

The open-access MAF lists 838 somatic variants for this specimen: 639 protein-altering or splice-affecting, 182 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 542, Silent 182, Nonsense Mutation 50, Frame Shift Del 21, Splice Site 16, RNA 7, Splice Region 5, Intron 4, Frame Shift Ins 4, 3'UTR 3, 5'UTR 2, In Frame Del 1.

Variants (750 of 838; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 42/64 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 49/79 reads (62%) | catalogued as rs587781845, COSV52671445, COSV52701260, COSV52703282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.8240del p.P2747Hfs*22 | Frame Shift Del (DEL) | VAF 17/162 reads (10%) | catalogued as rs1553272201, COSV56347871; ClinVar: likely pathogenic; called by mutect2, pindel
- AASDHPPT | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV99593226; called by muse, mutect2, varscan2
- AASDHPPT | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99593227; called by muse, mutect2, varscan2
- AASS | c.2344G>T p.A782S | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.114); catalogued as COSV62791425; called by muse, mutect2, varscan2
- ABCA1 | c.3512A>G p.H1171R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs1486873520, COSV66069672; called by muse, mutect2, varscan2
- ABCA12 | c.1321T>A p.C441S (on ENST00000272895 / NM_173076.3; = p.C123S on NM_015657.3) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV55972380; called by muse, mutect2, varscan2
- ABCA13 | c.3785C>A p.A1262D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV70026493, COSV70041704; called by muse, mutect2, varscan2
- ABCB1 | c.3073G>T p.G1025C | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55961027; called by muse, mutect2, varscan2
- ABCB5 | c.3610G>T p.G1204* (on ENST00000404938 / NM_001163941.2; = p.G759* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 30/115 reads (26%) | catalogued as COSV51706440, COSV51718528; called by muse, mutect2, varscan2
- ABCC3 | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53327688; called by muse, mutect2, varscan2
- ACOT4 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV58336232; called by muse, mutect2, varscan2
- ACSM1 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV54639243; called by muse, mutect2, varscan2
- ACSM5 | c.1421T>C p.V474A | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs769546454, COSV59374170; called by muse, mutect2, varscan2
- ADAM2 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 146/292 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.506); catalogued as COSV55867078; called by muse, mutect2, varscan2
- ADAMTS12 | c.3047C>A p.P1016Q | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61255008; called by muse, mutect2, varscan2
- ADAMTS19 | c.1168C>A p.P390T | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV50786744; called by muse, mutect2, varscan2
- ADAMTS19 | c.2183C>A p.P728Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779874325, COSV50786910; called by muse, mutect2, varscan2
- ADAMTS5 | c.1499C>T p.T500I | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs955668523, COSV53184039; called by muse, mutect2, varscan2
- ADAMTS6 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV66866018; called by muse, mutect2, varscan2
- ADAMTS6 | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66864845; called by muse, mutect2, varscan2
- ADAMTS6 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV66863740, COSV66865944; called by muse, mutect2, varscan2
- ADCK2 | c.846C>A p.D282E | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.078); catalogued as rs201925626, COSV50783180; called by muse, mutect2, varscan2
- ADD3 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.398); catalogued as COSV53325253; called by muse, mutect2, varscan2
- ADGRF2 | c.1004C>A p.S335Y (on ENST00000296862 / NM_001368115.2; = p.S267Y on NM_153839.7) | Missense Mutation (SNP) | VAF 87/276 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV57291278; called by muse, mutect2
- ADGRL4 | c.803T>C p.I268T | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV66064804; called by muse, mutect2, varscan2
- AFDN | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 100/161 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as COSV60053932; called by muse, mutect2, varscan2
- AFF3 | c.256A>T p.R86* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV57869224; called by muse, mutect2, varscan2
- AFM | c.927G>T p.E309D | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as COSV56921752, COSV56922298; called by muse, mutect2, varscan2
- AGMO | c.695T>A p.I232K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs764772241, COSV61121971; called by muse, mutect2
- AGMO | c.693C>A p.C231* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100693867; called by muse, mutect2
- AGMO | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV61121978; called by muse, mutect2, varscan2
- AKAP3 | c.799A>G p.R267G | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV99961911; called by muse, mutect2, varscan2
- AKR1B15 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71152689; called by muse, mutect2, varscan2
- AL592490.1 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV69427532; called by muse, mutect2, varscan2
- ALPK2 | c.3454G>T p.D1152Y | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV64496170; called by muse, mutect2, varscan2
- ANAPC1 | c.4798C>T p.R1600W | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs779157640, COSV61978850; called by mutect2, varscan2
- ANKRD50 | c.2443A>G p.R815G | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72386183; called by muse, mutect2, varscan2
- ANKRD7 | c.182C>G p.T61R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54556284; called by muse, mutect2, varscan2
- ANKS1B | c.168C>A p.D56E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61370691; called by muse, mutect2, varscan2
- ANO7 | c.1593G>T p.R531S (on ENST00000274979; = p.R477S on NM_001370694.2) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.253); catalogued as COSV51477933, COSV51479337; called by muse, mutect2, varscan2
- AP002512.3 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.169); catalogued as rs767591636, COSV54408474, COSV99688220; called by muse, mutect2, varscan2
- ARFGEF2 | c.2998G>T p.E1000* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | catalogued as COSV100904129, COSV64214757; called by muse, mutect2, varscan2
- ARHGAP1 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV56321630; called by muse, mutect2, varscan2
- ARHGAP20 | c.1255G>T p.E419* | Nonsense Mutation (SNP) | VAF 33/129 reads (26%) | catalogued as COSV52817761; called by muse, mutect2, varscan2
- ARHGAP4 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs201244043, COSV63133864; called by muse, mutect2, varscan2
- ARHGEF12 | c.2740G>C p.D914H | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63106910; called by muse, mutect2, varscan2
- ARL10 | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs1392810335, COSV53799876; called by muse, mutect2, varscan2
- ARPP21 | c.1810G>A p.G604R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV51792153, COSV51806245; called by muse, mutect2, varscan2
- ASAH2 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 147/272 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as COSV61484293; called by muse, mutect2, varscan2
- ASTL | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs199510888, COSV60905260; called by muse, mutect2, varscan2
- ATF7IP | c.2686G>T p.G896* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | catalogued as COSV53776286; called by muse, mutect2, varscan2
- ATP11C | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.364); catalogued as COSV59571757; called by muse, mutect2, varscan2
- ATP8B4 | c.3124A>T p.N1042Y | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.197); catalogued as COSV52722497; called by muse, mutect2, varscan2
- ATRNL1 | c.1936G>T p.G646W | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as rs1235667975, COSV61814297; called by muse, mutect2, varscan2
- ATRNL1 | c.3189T>A p.S1063R | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV58110071; called by muse, mutect2, varscan2
- B3GALT2 | c.311T>A p.L104Q | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV66464477; called by muse, mutect2, varscan2
- BBS9 | c.1325T>G p.V442G | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs753543455, COSV54183539; called by muse, mutect2, varscan2
- BDH1 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64019582; called by muse, mutect2, varscan2
- BDP1 | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1364848156, COSV62433955; called by muse, mutect2, varscan2
- BDP1 | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV62433961; called by muse, mutect2, varscan2
- BICRA | c.2984C>G p.P995R | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV67606117; called by muse, mutect2
- BIVM-ERCC5 | c.2645G>T p.S882I | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV63246949; called by muse, mutect2, varscan2
- BOLL | c.223T>G p.Y75D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56576833; called by muse, mutect2, varscan2
- BPTF | c.5679G>T p.W1893C | Missense Mutation (SNP) | VAF 53/346 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58844973; called by muse, mutect2, varscan2
- BRCA1 | c.1603G>T p.G535* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV58783495, COSV58797286; called by muse, mutect2, varscan2
- BRDT | c.1474A>G p.R492G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV62866945; called by muse, mutect2, varscan2
- BRINP2 | c.1226C>A p.P409H | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64179650; called by muse, mutect2, varscan2
- C10orf82 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100980075; called by muse, mutect2, varscan2
- C10orf82 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100980077; called by muse, mutect2, varscan2
- C16orf71 | c.176C>T p.T59I | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV54794664; called by muse, mutect2, varscan2
- C18orf32 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 81/148 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59088296; called by muse, mutect2, varscan2
- C7orf57 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV62363877; called by muse, varscan2
- CACNA1E | c.2831A>T p.Q944L | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV62413940; called by muse, mutect2, varscan2
- CACNA1E | c.4382C>T p.P1461L | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62413949, COSV62438536; called by muse, mutect2, varscan2
- CALCRL | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as COSV66476868; called by muse, mutect2, varscan2
- CARM1 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 82/327 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549040186, COSV59002856; called by muse, mutect2, varscan2
- CARMIL2 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as COSV58030883; called by muse, mutect2
- CBARP | c.388G>A p.E130K (on ENST00000382477; = p.E136K on NM_152769.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV53067409, COSV53071288; called by mutect2, varscan2
- CBFA2T3 | c.1103G>C p.R368P | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV51923084, COSV51931840; called by muse, mutect2, varscan2
- CCDC102B | c.1088G>T p.W363L | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60151930, COSV99076762; called by muse, mutect2, varscan2
- CCDC178 | c.2311T>A p.L771I (on ENST00000383096 / NM_001105528.3; = p.L733I on NM_198995.3) | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV55792860; called by muse, mutect2, varscan2
- CCDC54 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV53759672; called by muse, mutect2, varscan2
- CCDC73 | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100066879; called by muse, mutect2, varscan2
- CCDC74B | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60103436; called by muse, mutect2, varscan2
- CCER1 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs755291593, COSV62648343; called by muse, mutect2, varscan2
- CCNI | c.244-2A>T p.X82_splice | Splice Site (SNP) | VAF 15/68 reads (22%) | catalogued as COSV52960699; called by muse, mutect2, varscan2
- CCSER1 | c.1744A>T p.T582S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61459795; called by muse, mutect2, varscan2
- CD28 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV60731457; called by muse, mutect2, varscan2
- CD34 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | catalogued as COSV60414652; called by muse, mutect2, varscan2
- CD81 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 65/86 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV55133981; called by muse, mutect2, varscan2
- CDC42BPG | c.4047G>C p.Q1349H | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61348837; called by muse, mutect2, varscan2
- CDH10 | c.1981G>T p.G661C | Missense Mutation (SNP) | VAF 89/155 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52581798; called by muse, mutect2, varscan2
- CDH19 | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs759627014, COSV100051553, COSV50972116; called by muse, mutect2, varscan2
- CDH8 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV54893584; called by muse, mutect2, varscan2
- CDK15 | c.1058+1G>T p.X353_splice (on ENST00000652192 / NM_001366386.2; = p.X302_splice on NM_139158.2) | Splice Site (SNP) | VAF 30/75 reads (40%) | catalogued as rs781412173, COSV53637484; called by muse, mutect2, varscan2
- CDR1 | c.138G>T p.M46I | Missense Mutation (SNP) | VAF 87/177 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV65164661; called by muse, mutect2, varscan2
- CELSR2 | c.7415G>A p.R2472H | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780688952, COSV54778180; called by muse, mutect2, varscan2
- CENPE | c.4198A>G p.T1400A | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs1373514175, COSV54388259; called by muse, mutect2, varscan2
- CEP128 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as rs747660649, COSV53672366; called by muse, mutect2, varscan2
- CEP192 | c.2504G>A p.R835K | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1264643593, COSV58064288; called by muse, mutect2, varscan2
- CEP350 | c.4745A>G p.D1582G | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs956198294, COSV62608604; called by muse, mutect2, varscan2
- CFAP69 | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV60187797; called by muse, mutect2, varscan2
- CFC1 | c.138C>A p.H46Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99383455; called by mutect2, varscan2
- CFHR5 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 92/161 reads (57%) | catalogued as rs781352172, COSV56827025; called by muse, mutect2, varscan2
- CHODL | c.738-1G>T p.X246_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV53047120; called by muse, mutect2, varscan2
- CHPF2 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV50398574; called by muse, mutect2, varscan2
- CLCA4 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV55370494; called by muse, mutect2, varscan2
- CLDN17 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54524392; called by muse, mutect2, varscan2
- CLK1 | c.818G>T p.C273F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); catalogued as COSV58432601; called by muse, mutect2, varscan2
- CMSS1 | c.212G>T p.R71M | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV70440559; called by muse, mutect2, varscan2
- CNDP1 | c.183C>A p.S61R | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62595041; called by muse, mutect2, varscan2
- CNTNAP5 | c.3799C>T p.Q1267* | Nonsense Mutation (SNP) | VAF 41/253 reads (16%) | catalogued as COSV70507334; called by muse, mutect2, varscan2
- COL11A1 | c.1999-1G>A p.X667_splice | Splice Site (SNP) | VAF 43/121 reads (36%) | catalogued as COSV62172611, COSV62179077, COSV62198366; called by muse, mutect2, varscan2
- COL11A1 | c.1847G>A p.G616D | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62194112; called by muse, mutect2, varscan2
- COL11A1 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV62194124; called by muse, mutect2, varscan2
- COL13A1 | c.1564C>T p.P522S (on ENST00000398978 / NM_001130103.2; = p.P465S on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV62573926; called by muse, mutect2, varscan2
- COL14A1 | c.1665G>T p.W555C | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52865442; called by muse, mutect2, varscan2
- COL21A1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.432); catalogued as COSV55176624; called by muse, mutect2, varscan2
- COL4A1 | c.4349G>T p.R1450M | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65430682; called by muse, mutect2, varscan2
- COL6A2 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55998741, COSV56014057; called by muse, mutect2, varscan2
- CPA1 | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1490781663, COSV50573788; called by muse, mutect2, varscan2
- CPS1 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1208452980, COSV51817249, COSV51821764; called by muse, mutect2, varscan2
- CPXM1 | c.2084C>A p.P695H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); catalogued as COSV66046269, COSV66046535; called by muse, mutect2, varscan2
- CPXM1 | c.833-2A>G p.X278_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | catalogued as COSV66046540; called by muse, mutect2, varscan2
- CRACD | c.2346del p.A783Qfs*46 | Frame Shift Del (DEL) | VAF 51/126 reads (40%) | catalogued as COSV51724158; called by pindel, varscan2
- CRB2 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 91/136 reads (67%) | SIFT tolerated (0.47); PolyPhen benign (0.102); catalogued as COSV100749575; called by muse, mutect2, varscan2
- CRTAM | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57070925; called by muse, mutect2, varscan2
- CSMD1 | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs760230512, COSV68248557; called by muse, mutect2, varscan2
- CSMD2 | c.3513G>T p.E1171D | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV53951970; called by muse, mutect2, varscan2
- CSMD3 | c.9884G>T p.G3295V (on ENST00000297405 / NM_001363185.1; = p.G3126V on NM_052900.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52289645; called by muse, mutect2, varscan2
- CSMD3 | c.5837del p.R1946Pfs*18 (on ENST00000297405 / NM_001363185.1; = p.R1842Pfs*18 on NM_052900.3) | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as COSV99828252; called by mutect2, pindel*, varscan2
- CSNK1A1L | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65790074; called by muse, mutect2, varscan2
- CTNNA2 | c.2764C>A p.P922T (on ENST00000402739 / NM_001282597.3; = p.P874T on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/241 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV58158502, COSV58174241; called by muse, mutect2, varscan2
- CTNND1 | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62385562; called by muse, mutect2, varscan2
- CWH43 | c.1656C>G p.H552Q | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs756008708, COSV56942906; called by muse, mutect2, varscan2
- CYLC1 | c.1193A>G p.K398R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV61415156; called by muse, mutect2
- CYP26B1 | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV50014022; called by muse, mutect2
- CYP2C9 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs12414460, CM1412015; called by muse, mutect2, varscan2
- CYP3A7 | c.176C>G p.T59R | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV60483035; called by muse, mutect2, varscan2
- CYP4F11 | c.919-2A>G p.X307_splice | Splice Site (SNP) | VAF 38/137 reads (28%) | catalogued as COSV56129114; called by muse, mutect2, varscan2
- DCAF12L1 | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64421692, COSV64422635; called by muse, mutect2, varscan2
- DCAF12L2 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV100758520, COSV63581089, COSV63583859; called by muse, mutect2, varscan2
- DCAF12L2 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | catalogued as COSV63580230, COSV63583864; called by muse, mutect2, varscan2
- DCAF4L2 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV60476952, COSV60481637; called by muse, mutect2, varscan2
- DCAF8 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.209); catalogued as COSV58783339, COSV58785586; called by muse, mutect2
- DCUN1D4 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 96/141 reads (68%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV58124760, COSV58125091; called by muse, mutect2, varscan2
- DDR1 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61320185, COSV61324474; called by muse, mutect2, varscan2
- DDX10 | c.2246G>T p.R749L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV59438952; called by muse, mutect2, varscan2
- DDX18 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as COSV54308681; called by muse, mutect2, varscan2
- DENND2A | c.943T>A p.S315T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV52057506; called by muse, mutect2, varscan2
- DGAT2L6 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as COSV100283926; called by muse, mutect2, varscan2
- DGKI | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229737763, COSV55970656; called by muse, mutect2, varscan2
- DIPK1C | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV59726333; called by muse, mutect2, varscan2
- DISP3 | c.2475G>T p.Q825H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV53835651; called by muse, mutect2, varscan2
- DLG4 | c.1700C>A p.T567K (on ENST00000399506 / NM_001321075.3; = p.T610K on NM_001365.4) | Missense Mutation (SNP) | VAF 106/325 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57241477; called by muse, mutect2, varscan2
- DLGAP4 | c.1344C>G p.S448R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV59422266; called by muse, mutect2, varscan2
- DMD | c.9954G>T p.E3318D | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58943656; called by muse, mutect2, varscan2
- DMD | c.5040C>A p.H1680Q | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63784209; called by muse, mutect2, varscan2
- DNAH10 | c.5883G>T p.Q1961H (on ENST00000409039; = p.Q1900H on NM_207437.3) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68999800; called by muse, mutect2, varscan2
- DNAH5 | c.4090G>T p.A1364S | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54246661; called by muse, mutect2, varscan2
- DOK6 | c.478A>T p.T160S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.753); catalogued as COSV66936332; called by muse, mutect2, varscan2
- DRC1 | c.1854G>T p.W618C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.525); catalogued as COSV55515866; called by muse, mutect2, varscan2
- DRD5 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58579956; called by muse, mutect2, varscan2
- DSCAM | c.2974C>A p.H992N | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV68033997; called by muse, mutect2, varscan2
- DSP | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 71/204 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV65795052; called by muse, mutect2, varscan2
- DSTYK | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs759554676, COSV65688163; called by muse, mutect2, varscan2
- DTX3 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 133/298 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV54084794, COSV54089846; called by muse, mutect2, varscan2
- DUOX1 | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58485409; called by muse, mutect2
- DUOX2 | c.4369A>T p.K1457* | Nonsense Mutation (SNP) | VAF 65/98 reads (66%) | catalogued as COSV66534131; called by muse, mutect2, varscan2
- DYRK4 | c.352G>T p.V118L | Missense Mutation (SNP) | VAF 79/128 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50543384; called by muse, mutect2, varscan2
- EFHB | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as COSV55552427; called by muse, mutect2, varscan2
- EHD1 | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57736345; called by muse, mutect2, varscan2
- EIF4E2 | c.179A>C p.Y60S | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV51473163; called by muse, mutect2, varscan2
- ELF4 | c.1858G>T p.G620C | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.557); catalogued as rs148636858, COSV57454428; called by muse, mutect2, varscan2
- ELMO1 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60304263, COSV60320230; called by muse, mutect2, varscan2
- ENOX2 | c.1009G>A p.A337T (on ENST00000338144 / NM_001382520.1; = p.A308T on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.342); catalogued as COSV57656926; called by muse, mutect2, varscan2
- EPB41L2 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61358227; called by muse, mutect2, varscan2
- EPHA5 | c.2986G>T p.A996S | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as COSV56637556; called by muse, mutect2, varscan2
- EPHA5 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56659683; called by muse, mutect2, varscan2
- EPHA6 | c.1738G>T p.E580* | Nonsense Mutation (SNP) | VAF 60/103 reads (58%) | catalogued as COSV67590508; called by muse, mutect2, varscan2
- ERICH3 | c.3383A>T p.N1128I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.423); catalogued as COSV58615727; called by muse, mutect2, varscan2
- ETNPPL | c.57G>T p.G19= | Splice Region (SNP) | VAF 29/64 reads (45%) | catalogued as COSV56597215; called by muse, mutect2, varscan2
- EXT1 | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV65483895; called by muse, mutect2, varscan2
- EYA1 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 36/164 reads (22%) | catalogued as COSV58166380; called by muse, mutect2, varscan2
- F9 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as CM940541, CM940542, CM940543, COSV54380883; called by muse, mutect2, varscan2
- F9 | c.839-2A>T p.X280_splice | Splice Site (SNP) | VAF 48/96 reads (50%) | catalogued as CS045822, COSV54382095; called by muse, mutect2, varscan2
- FAH | c.549T>G p.D183E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV55723320; called by muse, mutect2, varscan2
- FAM151B | c.33G>T p.W11C | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1030116434, COSV56474874; called by muse, mutect2, varscan2
- FAM155B | c.607A>C p.T203P | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52937543; called by muse, mutect2
- FAM172A | c.434C>G p.T145R | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs758327052, COSV67941112; called by muse, mutect2, varscan2
- FAM199X | c.1069C>G p.R357G | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV55434318; called by muse, mutect2, varscan2
- FAM47A | c.1778A>T p.E593V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV60499303; called by muse, mutect2, varscan2
- FAT2 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 78/331 reads (24%) | catalogued as COSV55827601; called by muse, varscan2
- FAT3 | c.7375C>A p.Q2459K | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.99); catalogued as rs778235189, COSV53162085; called by muse, mutect2, varscan2
- FCRL4 | c.249C>G p.Y83* | Nonsense Mutation (SNP) | VAF 93/194 reads (48%) | catalogued as COSV54865633; called by muse, mutect2, varscan2
- FGD1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64309468; called by muse, mutect2, varscan2
- FIBP | c.513-2A>G p.X171_splice | Splice Site (SNP) | VAF 83/204 reads (41%) | catalogued as rs1307100971, COSV57034181; called by muse, mutect2, varscan2
- FLG2 | c.1914G>T p.Q638H | Missense Mutation (SNP) | VAF 178/414 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV66172084; called by mutect2, varscan2
- FLG2 | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 366/765 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.045); catalogued as COSV66172089; called by muse, mutect2, varscan2
- FMO2 | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as rs765731423, COSV52949823; called by muse, mutect2, varscan2
- FNBP1L | c.84T>A p.Y28* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV53091076, COSV53096091; called by muse, mutect2, varscan2
- FOLH1 | c.2065C>A p.H689N | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV57047931, COSV57055181; called by muse, mutect2, varscan2
- FOXG1 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 112/429 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.533); catalogued as COSV57398952; called by muse, mutect2, varscan2
- FOXI1 | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60389765; called by muse, mutect2, varscan2
- FOXP1 | c.2022G>T p.E674D | Missense Mutation (SNP) | VAF 92/160 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV59552115; called by muse, mutect2, varscan2
- FRS3 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.687); catalogued as COSV52486169; called by muse, mutect2, varscan2
- FRS3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.489); catalogued as rs373318996, COSV52484258, COSV52485041; called by muse, mutect2, varscan2
- FSTL5 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV60222425, COSV60231556; called by mutect2, varscan2
- FYB1 | c.50A>G p.N17S | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV60954630; called by muse, mutect2, varscan2
- FZD10 | c.800C>A p.S267Y | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57475397; called by muse, mutect2, varscan2
- G6PC | c.764C>A p.T255N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as CM023374, COSV53832342; called by muse, mutect2, varscan2
- GABRG2 | c.1322A>C p.D441A (on ENST00000361925 / NM_001375343.1; = p.D401A on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV62721544; called by muse, mutect2, varscan2
- GABRQ | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100941316, COSV64783630; called by muse, mutect2, varscan2
- GBP6 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 75/302 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as COSV65012382; called by muse, mutect2, varscan2
- GDF6 | c.1152G>C p.E384D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs778407122, COSV54625147, COSV54625475, COSV99748079; called by muse, mutect2, varscan2
- GEMIN5 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV53563989; called by muse, mutect2
- GFPT1 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61950162; called by muse, mutect2, varscan2
- GH2 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 183/451 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60427648; called by muse, mutect2, varscan2
- GLI3 | c.2175C>A p.N725K | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV67893917; called by muse, mutect2, varscan2
- GOSR1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV56720344; called by muse, mutect2, varscan2
- GPA33 | c.905G>T p.R302M | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV63302001; called by muse, mutect2, varscan2
- GPR101 | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53239563; called by muse, mutect2, varscan2
- GRAMD1B | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 95/326 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as COSV59209520; called by muse, mutect2, varscan2
- GRIA3 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV52076955; called by muse, mutect2, varscan2
- GRIA3 | c.2504T>C p.L835P | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99989470; called by muse, mutect2, varscan2
- GRID2 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV99938885; called by muse, mutect2, varscan2
- GRIK1 | c.904C>A p.L302M | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.89); catalogued as COSV58729343; called by muse, mutect2, varscan2
- GRIK2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 125/396 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV100024393; called by muse, mutect2, varscan2
- GRIK2 | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 125/393 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV100024396, COSV59710691; called by muse, mutect2, varscan2
- GRM1 | c.2243C>A p.T748N | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51271794; called by muse, mutect2, varscan2
- GRM7 | c.1886G>T p.S629I | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63164388; called by muse, mutect2, varscan2
- GSK3B | c.983G>T p.R328L (on ENST00000264235 / NM_001146156.2; = p.R341L on NM_002093.4) | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51781385; called by muse, mutect2, varscan2
- GSPT2 | c.1748T>A p.I583N | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61214935; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2163G>C p.L721F (on ENST00000265755 / NM_016328.3; = p.L706F on NM_005685.4) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56090920; called by muse, mutect2, varscan2
- GTF3C1 | c.5668G>T p.D1890Y | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV62244266; called by muse, mutect2, varscan2
- GUCY1A2 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56498517; called by muse, mutect2, varscan2
- H2AC1 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV51236700, COSV51238081; called by muse, mutect2, varscan2
- HAPLN1 | c.899G>C p.G300A | Missense Mutation (SNP) | VAF 149/335 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.33); catalogued as COSV57148393, COSV57151256; called by muse, mutect2, varscan2
- HAVCR1 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 117/388 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.077); catalogued as rs779558770, COSV59402979; called by muse, mutect2, varscan2
- HCFC2 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV57560101; called by muse, mutect2, varscan2
- HCN4 | c.2577C>G p.I859M | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.143); catalogued as COSV56086682; called by muse, mutect2, varscan2
- HECW1 | c.2899C>A p.L967I | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV67838200; called by muse, mutect2, varscan2
- HERC6 | c.2184G>T p.M728I | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52033743; called by muse, mutect2, varscan2
- HNRNPD | c.1032G>T p.R344S (on ENST00000313899 / NM_031370.3; = p.R295S on NM_002138.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV58314668; called by muse, mutect2, varscan2
- HNRNPU | c.781G>T p.E261* (on ENST00000283179; = p.E323* on NM_004501.3) | Nonsense Mutation (SNP) | VAF 33/105 reads (31%) | catalogued as COSV51693636; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1190G>C p.R397P | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV57133552; called by muse, mutect2, varscan2
- HOATZ | c.484C>A p.Q162K (on ENST00000375618 / NM_001100388.1; = p.Q189K on NM_207430.2) | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60442294; called by muse, mutect2, varscan2
- HOXA3 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.753); catalogued as COSV100415756, COSV57827995, COSV57828442; called by muse, varscan2
- HS3ST5 | c.161C>G p.A54G | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV57149372; called by muse, mutect2, varscan2
- HSD11B1 | c.816C>A p.C272* | Nonsense Mutation (SNP) | VAF 140/268 reads (52%) | catalogued as COSV54829250; called by muse, mutect2, varscan2
- HSD3B2 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 121/254 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV65593883; called by muse, mutect2, varscan2
- ICE1 | c.3700G>T p.E1234* | Nonsense Mutation (SNP) | VAF 6/87 reads (7%) | catalogued as COSV56830750; called by muse, mutect2
- IL2RG | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as CM159961, COSV52149963; called by muse, mutect2, varscan2
- IL7R | c.1170C>A p.C390* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV100286701, COSV57412269; called by muse, mutect2, varscan2
- IMPG2 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 48/72 reads (67%) | catalogued as COSV51984071, COSV51984524; called by muse, mutect2, varscan2
- INHBA | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.278); catalogued as COSV54220880; called by muse, varscan2
- INHBE | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV56988786; called by muse, mutect2, varscan2
- INSRR | c.730C>A p.R244S | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs752256376, COSV63876638; called by muse, mutect2, varscan2
- IPCEF1 | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 129/213 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54550029; called by muse, mutect2, varscan2
- IQSEC2 | c.2396G>T p.S799I (on ENST00000642864 / NM_001111125.3; = p.S594I on NM_015075.2) | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64727638; called by muse, mutect2, varscan2
- IRF6 | c.343G>T p.D115Y | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as CD133896, COSV65420211; called by muse, mutect2, varscan2
- ITGAM | c.1634G>A p.G545E (on ENST00000648685 / NM_001145808.2; = p.G544E on NM_000632.4) | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54940227; called by muse, mutect2, varscan2
- ITIH5 | c.1419G>T p.G473= | Splice Region (SNP) | VAF 28/86 reads (33%) | catalogued as COSV53672343; called by muse, mutect2
- JAG2 | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 169/340 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59312195; called by muse, mutect2, varscan2
- JAKMIP1 | c.2131G>T p.E711* | Nonsense Mutation (SNP) | VAF 21/35 reads (60%) | catalogued as COSV68955550; called by muse, mutect2, varscan2
- JAM2 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57258600, COSV57260148; called by muse, mutect2, varscan2
- JHY | c.1969C>G p.L657V | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57079146; called by muse, mutect2, varscan2
- KATNIP | c.194T>A p.L65* | Nonsense Mutation (SNP) | VAF 45/156 reads (29%) | catalogued as COSV55189674; called by muse, mutect2, varscan2
- KCNH1 | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55098136; called by muse, mutect2, varscan2
- KCNH5 | c.1655G>T p.R552L | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs778225685, COSV59760575, COSV59779000; called by muse, mutect2, varscan2
- KCNK1 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as COSV64039611; called by muse, mutect2, varscan2
- KIAA0319 | c.1627C>G p.Q543E | Missense Mutation (SNP) | VAF 176/908 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65501575; called by muse, mutect2, varscan2
- KIAA1210 | c.2447C>A p.S816* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV68179521; called by muse, mutect2, varscan2
- KIF18A | c.1497G>T p.E499D | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV54186861; called by muse, mutect2, varscan2
- KIF26B | c.6253G>A p.E2085K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV63649657; called by muse, mutect2, varscan2
- KIF2B | c.1823A>G p.D608G | Missense Mutation (SNP) | VAF 104/278 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as COSV52134529; called by muse, mutect2, varscan2
- KIF5A | c.1413C>A p.S471R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV54058175; called by muse, mutect2, varscan2
- KIRREL2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 75/112 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52879425; called by muse, mutect2, varscan2
- KLHL28 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61889211; called by muse, mutect2, varscan2
- KLHL7 | c.1613G>T p.G538V (on ENST00000339077 / NM_001031710.3; = p.G490V on NM_018846.5) | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59163994; called by muse, mutect2, varscan2
- KLK5 | c.442C>G p.P148A | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV100306937; called by muse, mutect2, varscan2
- KLK5 | c.441C>A p.H147Q | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV100306942, COSV100306946; called by muse, mutect2, varscan2
- KLK8 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs757597384, COSV51593460; called by muse, mutect2, varscan2
- KMT2D | c.2812C>G p.P938A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56418630, COSV56477543; called by muse, mutect2
- KPRP | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs773354173, COSV100908733, COSV64221808, COSV64222753; called by muse, mutect2, varscan2
- KRT2 | c.404T>A p.L135* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100548365; called by muse, mutect2, varscan2
- KRT2 | c.403T>A p.L135I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100548368; called by muse, mutect2, varscan2
- KRT3 | c.827T>A p.L276Q | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100526847, COSV58816918; called by muse, mutect2, varscan2
- KRT6A | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58107309; called by muse, mutect2, varscan2
- KRT6A | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.137); catalogued as rs201221663, COSV58106002; called by muse, mutect2, varscan2
- KRT83 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53342142; called by muse, mutect2, varscan2
- KRTAP13-1 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV62664192; called by muse, mutect2, varscan2
- KRTAP4-3 | c.17G>T p.C6F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66941015; called by muse, mutect2, varscan2
- KSR1 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100122765; called by muse, mutect2
- LEPR | c.1889A>T p.Y630F | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); catalogued as COSV60762367; called by muse, mutect2, varscan2
- LINGO1 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV62438147; called by muse, mutect2, varscan2
- LMX1B | c.1205C>G p.S402C (on ENST00000373474 / NM_001174147.2; = p.S395C on NM_002316.4) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62741447; called by muse, mutect2, varscan2
- LPCAT2 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs769905761, COSV50898825; called by muse, mutect2, varscan2
- LRFN1 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as rs745531312, COSV50497231; called by muse, mutect2, varscan2
- LRFN5 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53246728, COSV53249885; called by muse, mutect2, varscan2
- LRP1B | c.11455A>T p.N3819Y | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.312); catalogued as COSV67263391; called by muse, mutect2, varscan2
- LRRC4 | c.1475C>A p.T492K | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV50817410; called by muse, mutect2, varscan2
- LRRC4 | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as COSV50817451; called by muse, mutect2, varscan2
- LRRC4C | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV53435662; called by muse, mutect2, varscan2
- LRRC7 | c.3482C>T p.T1161I (on ENST00000651989 / NM_001370785.2; = p.T1128I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV50588040; called by muse, mutect2, varscan2
- LRRN3 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142475039; called by muse, mutect2, varscan2
- LRRTM4 | c.899G>T p.W300L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV69141610; called by muse, mutect2, varscan2
- LTN1 | c.4221-1G>T p.X1407_splice | Splice Site (SNP) | VAF 47/95 reads (49%) | catalogued as COSV63735020; called by muse, mutect2, varscan2
- LY6D | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV56661659; called by muse, mutect2, varscan2
- MAGEA6 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV61448901, COSV61449327; called by muse, mutect2, varscan2
- MAGEC3 | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV53577170, COSV68924182; called by muse, mutect2
- MAPK4 | c.1035C>G p.S345R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs749227781, COSV68543473; called by muse, mutect2, varscan2
- MAPKBP1 | c.693C>A p.N231K | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV52966332; called by muse, mutect2, varscan2
- MARCHF1 | c.361C>G p.R121G (on ENST00000274056; = p.R104G on NM_017923.4) | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56819266, COSV56829091; called by muse, mutect2, varscan2
- MARF1 | c.4225C>T p.R1409* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as COSV60025033; called by muse, mutect2, varscan2
- MBNL3 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); catalogued as COSV63731508; called by muse, mutect2, varscan2
- MC2R | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV59620026; called by muse, varscan2
- MCM6 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV51468821; called by muse, mutect2, varscan2
- MCM7 | c.583-1G>T p.X195_splice | Splice Site (SNP) | VAF 30/79 reads (38%) | catalogued as COSV57998487; called by muse, mutect2, varscan2
- MDGA2 | c.981G>T p.E327D (on ENST00000399232 / NM_001113498.2; = p.E29D on NM_182830.4) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV62111420; called by muse, mutect2, varscan2
- MDN1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV65528660; called by muse, mutect2, varscan2
- MEI1 | c.1440G>T p.R480S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs756386772, COSV55906564; called by muse, mutect2, varscan2
- MESP1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1397426250, COSV55588619; called by muse, mutect2, varscan2
- MGA | c.4148G>T p.R1383L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV54961299, COSV99579909; called by muse, mutect2, varscan2
- MGAM | c.3953C>G p.P1318R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075427; called by muse, mutect2
- MGAT5 | c.1657G>T p.G553C | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56100200; called by muse, mutect2, varscan2
- MGAT5B | c.1732-1G>T p.X578_splice (on ENST00000569840 / NM_001199172.2; = p.X576_splice on NM_144677.3) | Splice Site (SNP) | VAF 168/276 reads (61%) | catalogued as COSV56935315; called by muse, mutect2, varscan2
- MLH3 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1409969294, COSV53135749; called by muse, mutect2, varscan2
- MLXIPL | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs782531233, COSV57670016; called by muse, mutect2, varscan2
- MME | c.1320C>T p.V440= | Splice Region (SNP) | VAF 16/61 reads (26%) | catalogued as rs770000057, COSV64706305, COSV64706635; called by muse, mutect2, varscan2
- MMP13 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | catalogued as COSV52825273; called by muse, mutect2, varscan2
- MNDA | c.495C>G p.S165R | Missense Mutation (SNP) | VAF 166/510 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.505); catalogued as rs1156496876, COSV63740596, COSV63741868; called by muse, mutect2, varscan2
- MRGPRX4 | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100049679, COSV58589877; called by muse, mutect2, varscan2
- MRGPRX4 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as rs754982763, COSV100049638; called by muse, mutect2, varscan2
- MSC | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV57696409; called by muse, mutect2, varscan2
- MTMR8 | c.1649C>A p.T550N | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1374309627, COSV66395893; called by muse, mutect2, varscan2
- MUC4 | c.2810C>A p.P937H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV62186427; called by muse, mutect2, varscan2
- MYBPH | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV55143889; called by muse, mutect2, varscan2
- MYH2 | c.2990A>T p.K997M | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55446576; called by muse, mutect2, varscan2
- MYL2 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV57407909; called by muse, varscan2
- MYLK | c.3373C>A p.P1125T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100658922, COSV60619762; called by muse, mutect2, varscan2
- MYLK | c.165G>T p.R55= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as COSV60619775; called by muse, mutect2, varscan2
- MYLK4 | c.340G>C p.G114R | Missense Mutation (SNP) | VAF 85/577 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as COSV51149254; called by muse, mutect2, varscan2
- MYO7A | c.1237A>T p.K413* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV68686686; called by muse, mutect2, varscan2
- MYOCD | c.480T>A p.D160E | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.063); catalogued as COSV58510404; called by muse, mutect2, varscan2
- NAGPA | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | PolyPhen probably damaging (1); catalogued as rs1234150276, COSV56570722, COSV99044133; called by muse, mutect2, varscan2
- NALCN | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs569850296, COSV51915517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NASP | c.868G>T p.G290C | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV63113229, COSV63114450; called by muse, mutect2, varscan2
- NAV3 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 85/351 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.598); catalogued as COSV57106112; called by muse, mutect2, varscan2
- NBEA | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV59815167; called by muse, mutect2, varscan2
- NBEAL1 | c.4660G>T p.D1554Y | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV71375292; called by muse, mutect2, varscan2
- NCKAP5 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58446567, COSV58455764; called by muse, mutect2, varscan2
- NEU3 | c.926C>G p.P309R | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.12); catalogued as rs774103340, COSV53638613; called by muse, mutect2, varscan2
- NEUROD1 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV54550811, COSV54551556; called by muse, mutect2, varscan2
- NLGN1 | c.1328G>A p.W443* | Nonsense Mutation (SNP) | VAF 52/87 reads (60%) | catalogued as COSV64344244; called by muse, mutect2
- NLGN1 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as COSV64344250; called by muse, mutect2
- NLRP14 | c.2146G>T p.D716Y | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV55063727, COSV55071114; called by muse, mutect2, varscan2
- NME8 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52254589; called by muse, mutect2, varscan2
- NMUR2 | c.1035C>A p.F345L | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54921910; called by muse, mutect2, varscan2
- NOBOX | c.317T>A p.L106Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.799); catalogued as COSV56197087; called by muse, mutect2, varscan2
- NOL4 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52339495, COSV52352073, COSV52358887; called by muse, mutect2, varscan2
- NOS1 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV57619783; called by muse, mutect2, varscan2
- NOX4 | c.1642G>T p.G548* | Nonsense Mutation (SNP) | VAF 31/100 reads (31%) | catalogued as COSV54462297; called by muse, mutect2, varscan2
- NPAP1 | c.1781G>T p.S594I | Missense Mutation (SNP) | VAF 56/86 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as COSV61510435; called by muse, mutect2
- NPTXR | c.1375C>A p.L459M | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.97); catalogued as COSV60729349; called by muse, mutect2, varscan2
- NPY1R | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV56715994; called by muse, mutect2, varscan2
- NR4A2 | c.91A>T p.S31C | Missense Mutation (SNP) | VAF 64/107 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV59895268; called by muse, mutect2, varscan2
- NRSN1 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65894432; called by muse, mutect2, varscan2
- NRXN1 | c.2762T>G p.L921W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58484615; called by muse, mutect2, varscan2
- NUP210 | c.2659A>G p.I887V | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs761349540, COSV54412429; called by muse, mutect2, varscan2
- NUP42 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs937482627, COSV51730961; called by muse, mutect2, varscan2
- NUP85 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV55466277; called by muse, mutect2, varscan2
- OR10H4 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV59062736; called by muse, mutect2, varscan2
- OR14J1 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV65845930; called by muse, mutect2, varscan2
- OR14K1 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as COSV99315041; called by muse, mutect2, varscan2
- OR2T11 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58186959; called by muse, mutect2, varscan2
- OR2T33 | c.434C>A p.S145* | Nonsense Mutation (SNP) | VAF 80/333 reads (24%) | catalogued as COSV58815638, COSV58816435; called by muse, mutect2, varscan2
- OR2T6 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100861612, COSV63216953; called by muse, mutect2, varscan2
- OR4B1 | c.478G>T p.V160F | Missense Mutation (SNP) | VAF 78/117 reads (67%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.644); catalogued as rs780047019, COSV100535710, COSV58883728; called by muse, mutect2, varscan2
- OR4C16 | c.804G>T p.M268I | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV58942804, COSV58943865; called by muse, mutect2, varscan2
- OR4K1 | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV53462071; called by muse, mutect2, varscan2
- OR51I2 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58298913, COSV58300081; called by muse, mutect2, varscan2
- OR5D14 | c.785G>C p.C262S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV59458043; called by muse, mutect2, varscan2
- OR6N2 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as COSV59412789; called by muse, mutect2, varscan2
- PACRG | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1212278700, COSV61308713, COSV61315792; called by muse, mutect2, varscan2
- PADI4 | c.1159C>A p.P387T | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64924880; called by muse, mutect2, varscan2
- PALM | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs1361290769, COSV52770487; called by muse, mutect2, varscan2
- PANX1 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV57134826; called by muse, mutect2, varscan2
- PAPPA | c.3379G>T p.D1127Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV60290279; called by muse, mutect2, varscan2
- PARVB | c.692+1G>T p.X231_splice | Splice Site (SNP) | VAF 42/241 reads (17%) | catalogued as COSV58690704; called by muse, mutect2, varscan2
- PCARE | c.2665C>A p.L889M | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV59057180; called by muse, mutect2, varscan2
- PCDH11X | c.1539C>G p.F513L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53496834; called by muse, mutect2, varscan2
- PCDH15 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57377279; called by muse, mutect2, varscan2
- PCDHA10 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 118/391 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as rs781903292, COSV56537978; called by muse, mutect2, varscan2
- PCDHA3 | c.2304C>A p.D768E | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV63545189; called by muse, mutect2, varscan2
- PCDHB4 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 62/358 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs782002840, COSV52026023; called by muse, varscan2
- PCDHGA2 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54013515; called by muse, mutect2, varscan2
- PCDHGA8 | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV54013542; called by muse, mutect2, varscan2
- PCDHGB1 | c.734G>T p.R245M | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV54013526; called by muse, mutect2, varscan2
- PCDHGB5 | c.1642G>T p.V548L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV54013555; called by muse, mutect2, varscan2
- PCNX2 | c.2171A>C p.E724A | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV50861998; called by muse, mutect2, varscan2
- PCSK4 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 57/90 reads (63%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); catalogued as COSV56301030; called by muse, mutect2, varscan2
- PDE10A | c.1313A>T p.Y438F | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV63104188; called by muse, mutect2, varscan2
- PDE11A | c.1603G>T p.D535Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53705683, COSV99615853; called by muse, mutect2, varscan2
- PDE11A | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV53705706; called by muse, mutect2, varscan2
- PDGFRA | c.962T>A p.F321Y | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as COSV57272440; called by muse, mutect2, varscan2
- PDLIM5 | c.102A>T p.K34N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV58751800; called by muse, mutect2, varscan2
- PDZRN3 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55213115; called by muse, mutect2
- PGR | c.2321A>C p.Q774P | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV54809074; called by muse, mutect2, varscan2
- PGRMC1 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54293287, COSV54293467; called by muse, mutect2, varscan2
- PHACTR3 | c.345G>C p.E115D | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs781220541, COSV63033151; called by muse, mutect2, varscan2
- PHKA1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59801926, COSV59801951; called by muse, mutect2, varscan2
- PIK3R4 | c.2647G>T p.V883L | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100768304; called by muse, mutect2, varscan2
- PIK3R4 | c.2646G>T p.E882D | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.043); catalogued as COSV63244981; called by muse, mutect2, varscan2
- PIP4P2 | c.635_636insT p.T213Hfs*53 | Frame Shift Ins (INS) | VAF 9/62 reads (15%) | catalogued as COSV99575221; called by mutect2, pindel, varscan2
- PKHD1L1 | c.3562G>T p.V1188F | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV65750696; called by muse, mutect2, varscan2
- PKP1 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs201459638; called by muse, mutect2, varscan2
- PKP2 | c.751A>T p.S251C | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50744295; called by muse, mutect2, varscan2
- PLA2G2A | c.190T>C p.C64R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64287592; called by muse, mutect2, varscan2
- PLA2G4A | c.775G>C p.V259L | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV66556277; called by muse, mutect2, varscan2
- PLA2R1 | c.4144G>C p.D1382H | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV51785278; called by muse, mutect2, varscan2
- PLD4 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66915619; called by muse, mutect2, varscan2
- PLEC | c.10825G>T p.G3609C (on ENST00000322810 / NM_201380.4; = p.G3499C on NM_000445.5) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59683870; called by muse, mutect2, varscan2
- PLP2 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV66240526; called by muse, mutect2, varscan2
- PLXDC2 | c.1559A>T p.K520I | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV65907228, COSV65907995; called by muse, mutect2, varscan2
- POLA1 | c.421T>A p.C141S | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV66890004; called by muse, mutect2, varscan2
- POM121L12 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV68694084; called by muse, mutect2, varscan2
- PPDPFL | c.105C>A p.N35K | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as COSV57462067; called by muse, mutect2, varscan2
- PPFIA2 | c.3640G>T p.G1214W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV61049856; called by muse, mutect2, varscan2
- PPM1B | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373245967; called by muse, mutect2, varscan2
- PPP2R2B | c.1151C>A p.P384H (on ENST00000394409; = p.P450H on NM_181674.2) | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV60775901; called by muse, mutect2, varscan2
- PPP2R3B | c.1514A>T p.Y505F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as COSV66814265; called by muse, mutect2, varscan2
- PRDM9 | c.1168T>C p.C390R | Missense Mutation (SNP) | VAF 76/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs765042027, COSV57011825; called by muse, mutect2, varscan2
- PRICKLE1 | c.508T>C p.Y170H | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61546058; called by muse, mutect2, varscan2
- PRKAA2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 101/203 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV64806068; called by muse, mutect2, varscan2
- PRKAG3 | c.439T>A p.C147S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52103443; called by muse, mutect2, varscan2
- PRKCG | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV54727739; called by muse, mutect2, varscan2
- PRKD1 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV59582407; called by muse, mutect2, varscan2
- PRKN | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 98/152 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58260343; called by muse, mutect2, varscan2
- PROSER1 | c.2581G>T p.A861S | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV61489214; called by muse, mutect2, varscan2
- PTCHD3 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV71256811, COSV71257218; called by muse, mutect2
- PTPN14 | c.998A>C p.Q333P | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as COSV65287403; called by muse, mutect2
- PTPRU | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV60534976, COSV60535271; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1712G>T p.S571I | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100365212; called by muse, mutect2, varscan2
- RAB11FIP5 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 130/651 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50256071; called by muse, mutect2, varscan2
- RAB20 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57441039, COSV57441821; called by muse, mutect2, varscan2
- RABGAP1L | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 25/184 reads (14%) | catalogued as COSV99268864; called by muse, mutect2, varscan2
- RABGAP1L | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV99268868; called by muse, mutect2, varscan2
- RABL2A | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV64573442; called by muse, mutect2, varscan2
- RARS1 | c.978G>T p.L326F | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51564643, COSV99199073; called by muse, mutect2, varscan2
- RARS1 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99199074; called by muse, mutect2, varscan2
- RASAL2 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 49/398 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.045); catalogued as COSV62721351; called by muse, mutect2, varscan2
- RASD2 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 211/295 reads (72%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs974992841, COSV53353412, COSV53353432; called by muse, mutect2, varscan2
- RASGRF2 | c.2563A>C p.T855P | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV54137471; called by muse, mutect2, varscan2
- RASL12 | c.570C>G p.S190R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV54982497, COSV54982986; called by muse, mutect2, varscan2
- RBM10 | c.1886C>T p.T629I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV61311572; called by muse, mutect2
- RBMXL1 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as COSV53104834; called by muse, mutect2, varscan2
- RELN | c.8695G>T p.E2899* | Nonsense Mutation (SNP) | VAF 30/156 reads (19%) | catalogued as COSV59028740; called by muse, mutect2, varscan2
- REPIN1 | c.1358A>T p.H453L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68292850; called by muse, mutect2
- RGS21 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV101313998; called by muse, mutect2, varscan2
- RGS21 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV101313999, COSV69883489; called by muse, mutect2, varscan2
- RHBDD1 | c.473G>T p.C158F | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV58124311, COSV58130737; called by muse, mutect2, varscan2
- RHOBTB2 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV52572786; called by muse, mutect2, varscan2
- RNF149 | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV54863185, COSV54865169; called by muse, mutect2, varscan2
- RP1L1 | c.1200G>T p.Q400H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV66759179; called by muse, varscan2
- RP1L1 | c.1130C>G p.S377* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV66759184; called by muse, varscan2
- RPGRIP1L | c.2059A>T p.S687C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV50914419; called by muse, mutect2, varscan2
- RPS6KA6 | c.2045G>T p.W682L | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53125416; called by muse, mutect2, varscan2
- RTL8B | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66954418; called by muse, mutect2, varscan2
- RTL9 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV71826170; called by muse, mutect2, varscan2
- RTP5 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV58321526; called by muse, mutect2, varscan2
- RXFP3 | c.1081C>A p.Q361K | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57507490; called by muse, mutect2, varscan2
- SAA2 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.171); catalogued as COSV56777904; called by muse, mutect2, varscan2
- SALL1 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV51763231; called by muse, mutect2, varscan2
- SAMD4B | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV58751755; called by muse, mutect2, varscan2
- SAP130 | c.589C>A p.H197N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV52101509; called by muse, mutect2, varscan2
- SDHAF2 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57100008; called by muse, mutect2, varscan2
- SELP | c.1183G>C p.G395R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55256862, COSV99741558; called by muse, mutect2, varscan2
- SERGEF | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56386663; called by muse, mutect2, varscan2
- SERPINA3 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67586946; called by muse, mutect2, varscan2
- SERPINB10 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53074988; called by muse, mutect2, varscan2
- SERPINB12 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.526); catalogued as rs751796197, COSV54034666; called by muse, mutect2, varscan2
- SERPINB8 | c.935A>T p.K312M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV54640475; called by muse, mutect2, varscan2
- SERPINI2 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV52988433; called by muse, mutect2, varscan2
- SETBP1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56334201; called by muse, mutect2, varscan2
- SGIP1 | c.2265G>T p.K755N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV52775176, COSV52777196; called by muse, mutect2, varscan2
- SH3PXD2A | c.307G>C p.A103P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63513332; called by muse, mutect2, varscan2
- SH3PXD2B | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1408830667, COSV61129431; called by muse, mutect2, varscan2
- SHISAL1 | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.232); catalogued as COSV66988660, COSV66988993; called by muse, mutect2
- SHROOM2 | c.1582G>T p.D528Y | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV101098348; called by muse, mutect2, varscan2
- SHROOM4 | c.2964G>T p.M988I | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56795761; called by muse, mutect2, varscan2
- SKAP2 | c.470-1G>T p.X157_splice | Splice Site (SNP) | VAF 21/105 reads (20%) | catalogued as COSV61727035; called by muse, mutect2, varscan2
- SLC22A9 | c.466A>C p.M156L | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV54169770; called by muse, mutect2, varscan2
- SLC30A10 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 125/197 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63074531; called by muse, mutect2, varscan2
- SLC35E3 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as COSV60118371; called by muse, mutect2, varscan2
- SLC39A12 | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV66197944; called by muse, mutect2, varscan2
- SLC4A1 | c.2331G>T p.E777D | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.21); catalogued as COSV52262516; called by muse, mutect2, varscan2
- SLC5A12 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 311/989 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.477); catalogued as COSV54824190, COSV99745552; called by muse, mutect2, varscan2
- SLC8A3 | c.1867T>A p.W623R | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53691985; called by muse, mutect2, varscan2
- SLITRK6 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68391403; called by muse, mutect2, varscan2
- SLITRK6 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV68391410; called by muse, mutect2, varscan2
- SMARCA4 | c.1631A>C p.Q544P | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60805995; called by muse, mutect2, varscan2
- SMARCAL1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61923100; called by muse, mutect2, varscan2
- SMC2 | c.1487A>G p.Y496C | Missense Mutation (SNP) | VAF 113/166 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs751981726, COSV53963564; called by muse, mutect2, varscan2
- SMOC1 | c.1020C>A p.N340K | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV62762973; called by muse, mutect2, varscan2
- SMR3A | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 74/265 reads (28%) | catalogued as COSV56951151; called by muse, mutect2, varscan2
- SNAPC3 | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66460859; called by muse, mutect2, varscan2
- SNX8 | c.882A>T p.E294D | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56129539; called by muse, mutect2, varscan2
- SORCS1 | c.3076C>A p.P1026T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53874675, COSV53897854; called by muse, mutect2, varscan2
- SPART | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV62087804; called by muse, mutect2, varscan2
- SPATA31E1 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 59/85 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs779450573, COSV57791205; called by muse, mutect2, varscan2
- SPATS2 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.388); catalogued as COSV58922526; called by muse, mutect2, varscan2
- SPHKAP | c.3491T>C p.M1164T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs926864282, COSV60891424; called by muse, mutect2, varscan2
- SPTA1 | c.976A>G p.K326E | Missense Mutation (SNP) | VAF 162/417 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs1382292766, COSV63757963; called by muse, mutect2, varscan2
- SRGAP3 | c.3142G>T p.A1048S | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.017); catalogued as COSV100840780, COSV64538354; called by muse, mutect2
- SRPRA | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.213); catalogued as COSV55008563; called by muse, mutect2, varscan2
- SRRM2 | c.596G>T p.R199M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV57079334; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 26/138 reads (19%) | PolyPhen benign (0.003); catalogued as COSV60345877; called by muse, mutect2, varscan2
- ST8SIA2 | c.752G>T p.R251L | Missense Mutation (SNP) | VAF 49/78 reads (63%) | PolyPhen possibly damaging (0.738); catalogued as COSV51572264; called by muse, mutect2, varscan2
- STAG2 | c.2216A>G p.Y739C | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54369938; called by muse, mutect2, varscan2
- STAU2 | c.1081G>T p.A361S (on ENST00000524300 / NM_001164380.2; = p.A329S on NM_014393.2) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV63310919; called by muse, mutect2, varscan2
- STS | c.1289A>T p.Q430L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54271093; called by muse, mutect2, varscan2
- STYXL2 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV54809089, COSV99610022; called by muse, mutect2, varscan2
- STYXL2 | c.2916G>T p.E972D | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54809108; called by muse, mutect2, varscan2
- SUCO | c.3130A>G p.I1044V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as COSV55270080; called by muse, mutect2, varscan2
- SYN3 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60514777; called by muse, mutect2
- SYNE2 | c.3741G>T p.Q1247H | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV59965943, COSV59974238; called by muse, mutect2, varscan2
- SYT9 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 70/100 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59623762; called by muse, mutect2, varscan2
- TAB3 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55840122; called by mutect2, varscan2
- TAS2R40 | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV68818650; called by muse, mutect2, varscan2
- TCL1B | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as COSV61552291; called by muse, mutect2, varscan2
- TENM2 | c.5546T>C p.I1849T (on ENST00000518659 / NM_001122679.2; = p.I1610T on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV69138962; called by muse, mutect2, varscan2
- TENM4 | c.6966G>T p.K2322N | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV53657883; called by muse, mutect2, varscan2
- TERT | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV57234580; called by muse, mutect2
- TEX47 | c.503A>T p.K168M | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV51880065; called by muse, mutect2, varscan2
- TG | c.7274G>T p.S2425I | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV55090879; called by muse, mutect2, varscan2
- TIMP3 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56666313; called by muse, mutect2, varscan2
- TJP1 | c.1867G>T p.A623S | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV62045481; called by muse, mutect2, varscan2
- TLN2 | c.6270G>T p.K2090N | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.629); catalogued as COSV60894510; called by muse, mutect2, varscan2
- TMEM135 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV59700801; called by muse, mutect2, varscan2
- TMEM14C | c.236G>C p.R79T | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57639166; called by muse, mutect2, varscan2
- TMEM156 | c.881C>A p.P294Q | Missense Mutation (SNP) | VAF 74/108 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67929999; called by muse, mutect2, varscan2
- TMEM184A | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52475450; called by muse, mutect2, varscan2
- TMEM225 | c.22A>G p.S8G | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as COSV66693956; called by muse, mutect2, varscan2
- TMEM255A | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 40/143 reads (28%) | catalogued as COSV100550398, COSV59030965; called by muse, mutect2, varscan2
- TMEM255A | c.197T>A p.V66D | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59030994; called by muse, varscan2
- TMEM31 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV60328250, COSV99055981; called by muse, mutect2, varscan2
- TMEM52B | c.248C>A p.P83H (on ENST00000381923 / NM_001079815.1; = p.P63H on NM_153022.4) | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100046376, COSV53728283; called by muse, mutect2, varscan2
- TMEM59L | c.571A>G p.I191V | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53243290, COSV53243428; called by muse, mutect2, varscan2
- TMPRSS15 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as COSV99517355; called by muse, mutect2, varscan2
- TNN | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV53430609, COSV53433654, COSV99511160; called by muse, mutect2, varscan2
- TNN | c.3048G>A p.E1016= | Splice Region (SNP) | VAF 103/225 reads (46%) | catalogued as COSV53433668; called by muse, mutect2, varscan2
- TRANK1 | c.2095G>T p.V699F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV57161631; called by muse, mutect2, varscan2
- TRARG1 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV61563215; called by muse, mutect2, varscan2
- TREM2 | c.538G>C p.A180P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100632633, COSV58293842, COSV58295576; called by muse, mutect2, varscan2
- TRHDE | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.978); catalogued as COSV53861647; called by muse, mutect2, varscan2
- TRIM10 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs370559232; called by muse, varscan2
- TRIM10 | c.243C>A p.N81K | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.994); catalogued as COSV64990263; called by muse, varscan2
- TRIM33 | c.3126G>A p.M1042I | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.482); catalogued as COSV61825297; called by muse, varscan2
- TRIM51 | c.502T>A p.W168R | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV55270182; called by muse, mutect2, varscan2
- TRIM51 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV99792338; called by muse, mutect2, varscan2
- TRIM75P | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV72295895; called by muse, mutect2, varscan2
- TRIML1 | c.148C>G p.P50A | Missense Mutation (SNP) | VAF 56/309 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.253); catalogued as rs200213542, COSV60195119, COSV60196446; called by muse, mutect2, varscan2
- TRPC5 | c.789G>T p.R263S | Missense Mutation (SNP) | VAF 77/312 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.765); catalogued as COSV53296626, COSV53300773; called by muse, mutect2, varscan2
- TRPV5 | c.1736G>T p.G579V | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54688996; called by muse, mutect2, varscan2
- TSPAN32 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV51721828; called by muse, varscan2
- TTN | c.81109G>A p.D27037N (on ENST00000591111; = p.D19613N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | PolyPhen probably damaging (0.998); catalogued as rs761898404, COSV60284324; called by muse, mutect2, varscan2
- TTN | c.19108C>A p.L6370I (on ENST00000591111; = p.L5443I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | PolyPhen possibly damaging (0.654); catalogued as COSV60228515, COSV60284392; called by muse, mutect2, varscan2
- TTN | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | PolyPhen probably damaging (0.984); catalogued as COSV100591382, COSV100601515; called by muse, mutect2, varscan2
- TUB | c.541C>T p.L181F (on ENST00000299506 / NM_177972.3; = p.L236F on NM_003320.4) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV55108835; called by muse, mutect2, varscan2
- TYW1 | c.2074A>T p.S692C | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV100658533; called by muse, mutect2, varscan2
- UBD | c.299A>T p.K100M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV63544180; called by muse, mutect2, varscan2
- UBN2 | c.2584A>G p.I862V | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.891); catalogued as rs1376904011, COSV56034671; called by muse, mutect2, varscan2
- UBR4 | c.9123G>C p.K3041N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.066); catalogued as COSV64397045; called by muse, mutect2, varscan2
- UGT2A1 | c.98G>T p.W33L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54145760; called by muse, mutect2, varscan2
- ULK2 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64447888; called by muse, mutect2, varscan2
- UNC79 | c.6035G>T p.G2012V (on ENST00000393151 / NM_001346218.2; = p.G1835V on NM_020818.5) | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV56375060, COSV56405925; called by muse, mutect2, varscan2
- UNC79 | c.7903C>A p.L2635I (on ENST00000393151 / NM_001346218.2; = p.L2458I on NM_020818.5) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as COSV56405949; called by muse, mutect2, varscan2
- UNCX | c.314G>C p.R105P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV60333589, COSV99081995; called by muse, mutect2, varscan2
- URB2 | c.3635-2A>G p.X1212_splice | Splice Site (SNP) | VAF 24/134 reads (18%) | catalogued as COSV51025725; called by muse, mutect2, varscan2
- USH2A | c.7973C>A p.T2658K | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.915); catalogued as rs891321408, COSV56421516; called by muse, mutect2, varscan2
- USP24 | c.3775G>A p.D1259N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as rs761278282, COSV53776408; called by muse, mutect2, varscan2
- USP31 | c.2992G>T p.V998L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV54852165, COSV54856077; called by muse, mutect2, varscan2
- USP51 | c.721A>T p.T241S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.18); catalogued as COSV72351899; called by muse, mutect2, varscan2
- VCAN | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs750206974, COSV54114476; called by muse, mutect2, varscan2
- VPS36 | c.441+1G>T p.X147_splice | Splice Site (SNP) | VAF 43/141 reads (30%) | catalogued as COSV100955155; called by muse, mutect2, varscan2
- VPS36 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.072); catalogued as COSV100955157; called by muse, mutect2, varscan2
- VSTM2A | c.431C>A p.A144D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV56496250, COSV56496392; called by muse, mutect2, varscan2
- WDR59 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 40/242 reads (17%) | catalogued as COSV50942705; called by muse, mutect2, varscan2
- WWP2 | c.915-1G>T p.X305_splice | Splice Site (SNP) | VAF 29/127 reads (23%) | catalogued as COSV63127050; called by muse, mutect2, varscan2
- XIAP | c.481T>A p.Y161N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV63023599; called by muse, mutect2, varscan2
- XKR8 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.246); catalogued as COSV65835498; called by muse, mutect2, varscan2
- ZBTB33 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV58534876; called by muse, mutect2, varscan2
- ZC3H13 | c.1384A>T p.R462* | Nonsense Mutation (SNP) | VAF 40/137 reads (29%) | catalogued as COSV54461534; called by muse, mutect2, varscan2
- ZIC5 | c.1332C>G p.H444Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57438754; called by muse, mutect2, varscan2
- ZNF208 | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV68111476; called by muse, mutect2, varscan2
- ZNF215 | c.920A>T p.K307M | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV53494321, COSV53494574; called by muse, mutect2, varscan2
- ZNF257 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV71306181, COSV71311187; called by muse, mutect2, varscan2
- ZNF407 | c.5694G>T p.Q1898H | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV55266608; called by muse, mutect2, varscan2
- ZNF554 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV57886768; called by muse, mutect2, varscan2
- ZNF587 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57150491; called by muse, mutect2, varscan2
- ZNF630 | c.1744G>T p.G582* | Nonsense Mutation (SNP) | VAF 4/52 reads (8%) | catalogued as COSV52097930; called by muse, mutect2
- ZNF646 | c.2989G>T p.G997C | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV54926226; called by muse, mutect2, varscan2
- ZNF676 | c.776G>T p.C259F (on ENST00000650058; = p.C227F on NM_001001411.3) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68094622; called by muse, varscan2
- ZNF704 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100589408; called by muse, mutect2, varscan2
- ZNF704 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100589409; called by muse, mutect2, varscan2
- ZNF713 | c.401G>T p.W134L (on ENST00000633730 / NM_001366796.2; = p.W147L on NM_182633.3) | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs1481038066, COSV70057189; called by muse, mutect2, varscan2
- ZNF780B | c.2212A>T p.T738S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1414287588, COSV55467478; called by muse, mutect2, varscan2
- ZNF804B | c.1543C>A p.Q515K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV100305967, COSV60849167; called by muse, mutect2, varscan2
- ACSM2A | c.531del p.R178Efs*15 (on ENST00000219054; = p.R99Efs*15 on NM_001308169.2) | Frame Shift Del (DEL) | VAF 81/324 reads (25%) | called by mutect2, pindel, varscan2
- ANXA8 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.136); called by muse, varscan2
- APCDD1 | c.1470del p.R491Gfs*77 | Frame Shift Del (DEL) | VAF 68/221 reads (31%) | called by mutect2, pindel, varscan2
- ARHGAP36 | c.529del p.R177Gfs*50 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | called by mutect2, pindel, varscan2
- BCO2 | c.237del p.W79Cfs*41 | Frame Shift Del (DEL) | VAF 24/150 reads (16%) | called by mutect2, pindel, varscan2
- CHRNA1 | c.1245dup p.E416Rfs*23 (on ENST00000261007 / NM_001039523.3; = p.E391Rfs*23 on NM_000079.4) | Frame Shift Ins (INS) | VAF 30/116 reads (26%) | called by mutect2, pindel, varscan2
- CNGB3 | c.1805dup p.N602Kfs*34 | Frame Shift Ins (INS) | VAF 109/354 reads (31%) | called by pindel, varscan2
- DSPP | c.23del p.C8Sfs*5 | Frame Shift Del (DEL) | VAF 55/136 reads (40%) | called by mutect2, pindel, varscan2
- GSDMC | c.723_724del p.Y242Rfs*14 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- IGKV2-30 | c.220T>C p.Y74H | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- IGLV2-18 | c.324C>G p.Y108* | Nonsense Mutation (SNP) | VAF 156/270 reads (58%) | called by muse, mutect2
- INSM2 | c.874del p.R292Afs*68 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- LILRB2 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LILRB2 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LUM | c.803del p.N268Tfs*24 | Frame Shift Del (DEL) | VAF 35/154 reads (23%) | called by mutect2, pindel, varscan2
- MAP3K3 | c.1434del p.Y479Tfs*6 | Frame Shift Del (DEL) | VAF 156/449 reads (35%) | called by mutect2, pindel*, varscan2
- MC5R | c.148_165del p.S50_I55del | In Frame Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- PDZD2 | c.8031del p.S2678Hfs*5 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.5047del p.A1683Pfs*63 | Frame Shift Del (DEL) | VAF 200/731 reads (27%) | called by mutect2, pindel, varscan2
- SERPINB10 | c.938_940delinsTT p.D313Vfs*32 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | called by pindel, varscan2*
- SRL | c.857del p.P286Qfs*30 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- ST18 | c.2705del p.K902Rfs*9 | Frame Shift Del (DEL) | VAF 75/197 reads (38%) | called by mutect2, pindel, varscan2
- TAS2R3 | c.749_756del p.F250Cfs*5 | Frame Shift Del (DEL) | VAF 40/94 reads (43%) | called by mutect2, pindel, varscan2
- TBX21 | c.1174del p.D392Tfs*13 | Frame Shift Del (DEL) | VAF 52/147 reads (35%) | called by mutect2, pindel, varscan2
- TOGARAM1 | c.2273del p.G758Vfs*13 | Frame Shift Del (DEL) | VAF 29/158 reads (18%) | called by mutect2, pindel, varscan2
- UBC | c.1881dup p.S628Qfs*2 | Frame Shift Ins (INS) | VAF 90/400 reads (23%) | called by pindel, varscan2
- VIRMA | c.2207_2208del p.C736Sfs*4 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by pindel, varscan2
- ABCB11 | c.3807C>A p.T1269= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV55598618, COSV99793264; called by muse, mutect2, varscan2
- ABCB5 | c.2547C>T p.A849= (on ENST00000404938 / NM_001163941.2; = p.A404= on NM_178559.6) | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as rs779959892, COSV51718514, COSV99329110; called by muse, mutect2, varscan2
- AC100868.1 | c.927T>A p.S309= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as COSV51848766; called by muse, mutect2, varscan2
- ACE | c.2253C>T p.Y751= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV52012204; called by muse, mutect2, varscan2
- ADGRL2 | c.3003T>C p.I1001= (on ENST00000370717 / NM_001366005.1; = p.I988= on NM_012302.4) | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV54684097; called by muse, mutect2, varscan2
- AFM | c.1188C>T p.Y396= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs541901694, COSV56920111; called by muse, mutect2, varscan2
- AKR1B10 | c.84G>T p.V28= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV62056414; called by muse, mutect2, varscan2
- ALKBH1 | c.648A>T p.A216= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV53661003; called by muse, mutect2, varscan2
- ANKRD24 | c.1881C>T p.A627= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV53674971; called by muse, mutect2, varscan2
- APCDD1L | c.1011C>A p.T337= | Silent (SNP) | VAF 48/81 reads (59%) | catalogued as COSV64487714; called by muse, mutect2, varscan2
- ARFGEF2 | c.2997G>C p.L999= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as COSV100904126; called by muse, mutect2, varscan2
- ATP6V0A4 | c.402C>A p.T134= | Silent (SNP) | VAF 106/270 reads (39%) | catalogued as rs766656498, COSV59479457; called by muse, mutect2, varscan2
- ATP8B4 | c.237C>T p.T79= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs781387363, COSV52722507; called by muse, varscan2
- BARHL2 | c.732C>G p.L244= | Silent (SNP) | VAF 126/312 reads (40%) | catalogued as COSV64981890; called by muse, mutect2, varscan2
- BMP7 | c.852G>A p.T284= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs147083949; called by muse, mutect2, varscan2
- BPIFB4 | c.747G>A p.L249= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV64952131; called by muse, mutect2, varscan2
- C1QTNF6 | c.615G>T p.T205= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV55396027, COSV55397221; called by muse, mutect2, varscan2
- C3orf70 | c.630A>G p.G210= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV58590132; called by muse, mutect2, varscan2
- CACNA1D | c.756A>T p.S252= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV55461497; called by muse, mutect2, varscan2
- CALB1 | c.168T>A p.P56= | Silent (SNP) | VAF 38/170 reads (22%) | catalogued as COSV55369001; called by muse, varscan2
- CALCA | c.426A>G p.*142= | Silent (SNP) | VAF 109/320 reads (34%) | catalogued as COSV100523959; called by muse, mutect2, varscan2
- CALHM1 | c.741C>A p.I247= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1246414742, COSV53297082, COSV53297536; called by muse, mutect2, varscan2
- CASQ1 | c.693C>T p.F231= | Silent (SNP) | VAF 114/216 reads (53%) | catalogued as COSV63624473; called by muse, mutect2, varscan2
- CCDC34 | c.402G>A p.Q134= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV58726913; called by muse, mutect2, varscan2
- CCDC71L | c.690C>T p.F230= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs745971088, COSV60071163; called by muse, mutect2, varscan2
- CCDC73 | c.1101C>A p.S367= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100066876; called by muse, mutect2, varscan2
- CCM2L | c.60G>T p.V20= | Silent (SNP) | VAF 72/247 reads (29%) | catalogued as COSV52952163; called by muse, mutect2, varscan2
- CD101 | c.810C>T p.T270= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs773163352, COSV56720527, COSV99869985; called by muse, mutect2, varscan2
- CD300LG | c.996G>C p.A332= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs373493820, COSV53225369; called by muse, mutect2, varscan2
- CDH23 | c.570C>A p.I190= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as COSV54949197, COSV54952317; called by muse, mutect2, varscan2
- CDKL4 | c.921C>A p.R307= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV66510843; called by muse, mutect2, varscan2
- CEBPE | c.447G>T p.G149= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV52830578; called by muse, mutect2, varscan2
- CEP350 | c.589T>C p.L197= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV62486174; called by muse, mutect2, varscan2
- CFAP47 | c.2043C>T p.L681= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1389503706, COSV52890364; called by muse, mutect2, varscan2
- CHL1 | c.2058C>A p.V686= (on ENST00000397491 / NM_001253387.1; = p.V702= on NM_006614.4) | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV56603638; called by muse, mutect2, varscan2
- CLCA1 | c.234C>T p.A78= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as COSV52330494; called by muse, mutect2, varscan2
- CLCN1 | c.1674C>A p.P558= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs761240483, COSV58373675; called by muse, mutect2, varscan2
- CNTNAP5 | c.2448C>T p.S816= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as COSV70507331; called by muse, mutect2, varscan2
- COL4A6 | c.1356C>T p.N452= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100563703; called by muse, mutect2, varscan2
- CRACD | c.2358C>A p.T786= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV51729538; called by muse, varscan2
- CRB2 | c.123C>T p.A41= | Silent (SNP) | VAF 91/136 reads (67%) | catalogued as COSV100749576; called by muse, mutect2, varscan2
- CRISP3 | c.783C>A p.V261= (on ENST00000371159 / NM_001368123.1; = p.V243= on NM_006061.4) | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as COSV53822562; called by muse, mutect2, varscan2
- CSMD3 | c.8748G>A p.Q2916= (on ENST00000297405 / NM_001363185.1; = p.Q2747= on NM_052900.3) | Silent (SNP) | VAF 104/228 reads (46%) | catalogued as COSV52289672; called by muse, mutect2, varscan2
- DAB1 | c.1116C>A p.I372= (on ENST00000371231; = p.I339= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV64690645, COSV64697021; called by muse, mutect2, varscan2
- DCAF8 | c.553C>T p.L185= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV58785574; called by muse, mutect2
- DENND5B | c.2481A>G p.G827= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV60907188; called by muse, mutect2, varscan2
- DIO3 | c.324G>T p.L108= | Silent (SNP) | VAF 33/108 reads (31%) | catalogued as COSV63774398; called by muse, mutect2, varscan2
- DIP2C | c.600C>T p.H200= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as rs149263097; called by muse, mutect2, varscan2
- DLST | c.603A>T p.A201= | Silent (SNP) | VAF 64/123 reads (52%) | catalogued as COSV53167571; called by muse, mutect2, varscan2
- DMBT1 | c.3525C>A p.A1175= (on ENST00000338354 / NM_001377530.1; = p.A676= on NM_004406.3) | Silent (SNP) | VAF 193/389 reads (50%) | catalogued as rs1385532725, COSV57557825; called by muse, mutect2, varscan2
- DNAI1 | c.1233C>T p.Y411= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54283940; called by muse, mutect2, varscan2
- EBF3 | c.681C>A p.A227= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV62475914; called by muse, mutect2, varscan2
- ECEL1 | c.1245G>T p.P415= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV58813955; called by muse, mutect2, varscan2
- EDNRB | c.1236C>A p.A412= (on ENST00000377211 / NM_001201397.1; = p.A322= on NM_000115.5) | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV57527166; called by muse, mutect2, varscan2
- EEPD1 | c.615C>A p.T205= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV54202425; called by muse, mutect2, varscan2
- EGLN3 | c.159C>T p.T53= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV51656064; called by muse, mutect2, varscan2
- EIF5 | c.495C>A p.G165= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53686548; called by muse, mutect2
- EZHIP | c.720C>A p.A240= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV57957401; called by muse, mutect2, varscan2
- FAM155B | c.609G>T p.T203= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV52937550; called by muse, mutect2
- FAM3B | c.678A>T p.I226= | Silent (SNP) | VAF 127/265 reads (48%) | catalogued as COSV58098909; called by muse, mutect2, varscan2
- FBF1 | c.1065G>T p.L355= (on ENST00000586717; = p.L369= on NM_001319193.1) | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as COSV59866662; called by muse, mutect2, varscan2
- FBN2 | c.3150G>T p.T1050= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as COSV52499323, COSV52539164; called by muse, mutect2, varscan2
- FRMD4A | c.2634G>A p.L878= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV62268543; called by muse, mutect2, varscan2
- GIP | c.33G>T p.L11= | Silent (SNP) | VAF 31/238 reads (13%) | catalogued as COSV62467655; called by muse, mutect2, varscan2
- GNAS | c.921C>A p.P307= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV58348861; called by muse, mutect2, varscan2
- GPR158 | c.3099T>A p.A1033= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV66279932; called by muse, mutect2, varscan2
- GPR45 | c.399C>T p.F133= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as COSV51525801; called by muse, mutect2, varscan2
- GPR45 | c.739C>A p.R247= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as rs757651651, COSV51522993, COSV51525815; called by muse, mutect2, varscan2
- GPR82 | c.705G>T p.T235= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV56888092; called by muse, mutect2, varscan2
- GPRASP1 | c.225C>A p.R75= | Silent (SNP) | VAF 69/262 reads (26%) | catalogued as COSV64356313; called by mutect2, varscan2
- GRIA3 | c.2505G>T p.L835= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV99989476; called by muse, mutect2, varscan2
- GRID2 | c.315C>A p.L105= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as COSV99938883; called by muse, mutect2, varscan2
- GSDME | c.516G>A p.E172= | Silent (SNP) | VAF 78/317 reads (25%) | catalogued as COSV61652657; called by muse, mutect2, varscan2
- GTF2E1 | c.12A>T p.P4= | Silent (SNP) | VAF 118/181 reads (65%) | catalogued as COSV52205936; called by muse, mutect2, varscan2
- HAP1 | c.429C>G p.S143= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV57880308; called by muse, mutect2, varscan2
- HEATR1 | c.3333A>T p.T1111= | Silent (SNP) | VAF 83/152 reads (55%) | catalogued as COSV63982722; called by muse, mutect2, varscan2
- HEPH | c.1533C>A p.P511= (on ENST00000343002; = p.P244= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV57970372; called by muse, mutect2, varscan2
- HLA-F | c.102G>A p.S34= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1468929401, COSV52577031; called by muse, mutect2, varscan2
- HOXA3 | c.927C>A p.P309= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100415778, COSV57828432; called by muse, varscan2
- HTR2C | c.727C>A p.R243= | Silent (SNP) | VAF 179/743 reads (24%) | catalogued as COSV52221996; called by muse, mutect2, varscan2
- HTR5A | c.966C>T p.I322= | Silent (SNP) | VAF 34/221 reads (15%) | catalogued as COSV55286540; called by muse, mutect2, varscan2
- HYOU1 | c.2424G>T p.L808= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV68217121; called by muse, mutect2, varscan2
- IARS1 | c.2028A>T p.I676= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV65116781; called by muse, mutect2, varscan2
- IGFN1 | c.3453C>A p.P1151= (on ENST00000295591 / NM_001367841.1; = p.P3608= on NM_001164586.2) | Silent (SNP) | VAF 61/333 reads (18%) | catalogued as COSV55182333; called by muse, mutect2, varscan2
- IGHV4-28 | c.186G>T p.G62= | Silent (SNP) | VAF 103/274 reads (38%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.298C>T p.L100= | Silent (SNP) | VAF 104/425 reads (24%) | called by muse, mutect2, varscan2
- IGSF1 | c.2487C>G p.A829= | Silent (SNP) | VAF 176/853 reads (21%) | catalogued as COSV63839625; called by muse, mutect2, varscan2
- IPO5 | c.3129G>C p.A1043= | Silent (SNP) | VAF 60/375 reads (16%) | catalogued as rs749492889, COSV55157988, COSV55158752; called by muse, mutect2, varscan2
- ITGB8 | c.1461A>G p.L487= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as rs771385306, COSV56013143; called by muse, mutect2, varscan2
- KANK4 | c.2613G>A p.E871= | Silent (SNP) | VAF 41/198 reads (21%) | catalogued as rs774212372, COSV58093875; called by muse, mutect2, varscan2
- KCNF1 | c.1206C>A p.I402= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV54465256, COSV99705718; called by muse, mutect2, varscan2
- KIF13A | c.5292A>G p.L1764= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV52463020; called by muse, mutect2, varscan2
- KIF5A | c.171G>A p.T57= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs767814774, COSV54058163; called by muse, mutect2, varscan2
- KLHL14 | c.1011C>A p.L337= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV63835062; called by muse, mutect2, varscan2
- KRT16 | c.963C>A p.S321= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV56969365; called by muse, mutect2, varscan2
- KRTAP11-1 | c.471C>A p.S157= | Silent (SNP) | VAF 40/200 reads (20%) | catalogued as COSV60095190; called by muse, mutect2, varscan2
- L3MBTL3 | c.1308T>C p.L436= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as rs766051179, COSV62388414; called by muse, mutect2, varscan2
- LAIR1 | c.732G>T p.G244= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV57309365; called by muse, mutect2, varscan2
- LRATD1 | c.189C>A p.P63= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- LRGUK | c.2058A>T p.T686= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as rs752170911, COSV53642539; called by muse, mutect2, varscan2
- LY75 | c.1599T>C p.T533= | Silent (SNP) | VAF 7/147 reads (5%) | catalogued as rs1339689065, COSV55111857; called by muse, mutect2
- LY9 | c.393C>A p.A131= | Silent (SNP) | VAF 116/285 reads (41%) | catalogued as COSV54436971; called by muse, mutect2, varscan2
- MAGEB6 | c.447G>A p.Q149= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs752135139, COSV66872184; called by muse, mutect2, varscan2
- MC2R | c.723G>A p.L241= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV59620033, COSV59621584; called by muse, varscan2
- MIB2 | c.450G>T p.T150= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs369229242, COSV61757230; called by muse, mutect2
- MLC1 | c.30G>T p.L10= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV61118524; called by muse, mutect2, varscan2
- MOGAT1 | c.360G>C p.G120= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV71479915, COSV71480077; called by muse, mutect2, varscan2
- MOS | c.744G>A p.P248= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as rs766966951, COSV61336164, COSV61336874; called by muse, mutect2, varscan2
- MUC16 | c.38274C>A p.S12758= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV101198965; called by muse, mutect2, varscan2
- MUC17 | c.8460G>T p.T2820= | Silent (SNP) | VAF 142/735 reads (19%) | catalogued as rs140072363, COSV60300403; called by muse, mutect2, varscan2
- MYO16 | c.2643G>T p.A881= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV51813875; called by muse, mutect2, varscan2
88 further variants in this file (0 protein-altering or splice-affecting, 71 silent, 17 other) are not listed here.
